Gene-level copy-number profile of tumor specimen TCGA-06-0216-01A from TCGA case TCGA-06-0216, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: female; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 61.7 years (22,524 days).
Specimen TCGA-06-0216-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.2d571c14-98ed-4317-8d73-652bc90355f6.gene_level_copy_number.v36.tsv, workflow ASCAT2 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-06-0216-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 348 have no estimate.
https://portal.gdc.cancer.gov/files/43e9ab44-8972-42bb-ac03-cec09c95368c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 525; copy number 1: 541; copy number 2: 58,995; copy number 3: 121; copy number 4: 1; copy number 5: 7; copy number 6: 85.
ABSOLUTE estimates for another vial of this sample (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-06-0216-01B-01D-0333-01): tumor purity 0.91, ploidy 1.89, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 4 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:64,450,096–64,461,381, 2 genes (within-gene range 0–2): AC008074.1, LGALSL.
- chr6:285,443–351,355, 2 genes: AL365272.1, DUSP22.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 92 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:117,023,918–117,181,562, 5 genes, copy number 5: MTND1P28, MTND2P21, MTCO1P43, RNU7-190P, AC092170.1.
- chr13:19,026,001–19,032,626, 2 genes, copy number 5: GTF2IP3, AL137001.1.
- chr14:105,851,705–106,293,808, 85 genes, copy number 6 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 541. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
